Surgical pathology report (de-identified scan), TCGA case TCGA-43-2581, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-43-2581-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. Right upper lobe
- B. Level 11
- C. 2R
- D. 4R
- E. Level 7

CLINICAL NOTES

PRE-OP DIAGNOSIS: Lung cancer

GROSS DESCRIPTION

A. Received fresh in a container labeled "right upper lobe" is a 296 gm, 17.8 x 11.8 x 4 cm, lung lobe compatible with right upper lobe. In the hilar region there is an 0.8 cm long and 1.5 cm in diameter bronchial stump which is grossly unremarkable. The vessels at the margin are also grossly unremarkable. There are some tan-gray lymph nodes up to 1.2 cm in greatest dimension in the hilar region. The pleural surface is pink-purple with some anthracotic pigment deposition. There is some retraction of the pleural surface. The specimen is sectioned, and there is a 2.6 x 2 x 1.8 cm rubbery tan-white mass underlying the area with pleural retraction, with the mass suggestive of invading the pleura. Approximately 2 cm from this mass is a separate 4 x 3.5 x 3.1 cm rubbery tan-white mass. This mass approaches at least near to the pleural surface. The larger lesion has yellow-orange discoloration surrounding it, suggestive of surrounding pneumonia. The remainder of the parenchyma is spongy and red-purple without additional lesions. RS-13, following fixation.

BLOCK SUMMARY: A1 - bronchial margin; A2 - vascular margin; A3-A5 - first lesion described; A6-A9 - larger lesion; A10 - parenchyma surrounding larger lesion; A11- random lung; A12 - two hilar lymph nodes; A13 - bisected hilar lymph node.

GROSS DESCRIPTION

B. Received fresh in a container labeled "level 11" are two pieces of soft red-gray tissue, 0.7 cm in greatest aggregate dimension. AS-1, following fixation.

C. Received fresh in a container labeled "2R" are four pieces of soft red-gray tissue, 3 cm in greatest aggregate dimension. AS-2, following fixation.

D. Received fresh in a container labeled "4R" are multiple similar fragments of tissue, in aggregate 2.7 x 1 x 0.5 cm. AS-3, following fixation.

E. Received fresh in a container labeled "level 7" is a similar portion of tissue, 1.5 cm in greatest dimension. AS-2, following fixation.

MICROSCOPIC DESCRIPTION

The following template summarizes the findings in this case:

Histologic type: Both of the mass lesions consist of poorly differentiated non-small cell carcinoma. There are areas that it is favored have squamous differentiation, as well as less frequent foci suggestive of glandular differentiation (adenocarcinoma).

Although not entirely identical, the two lesions look similar.

Histologic grade: Poorly differentiated

Primary tumor (pT): These two lesions are grossly 2.6 cm and 4 cm in greatest dimension. The 2.6 cm in diameter lesion has visceral

[page 2 of 2]
pleural invasion, with the larger lesion extending very peripherally but without definite visceral pleural invasion. Although it is difficult to definitely distinguish between synchronous primaries and the two masses being part of the same process, given the similarities in appearance, based on the new guidelines, two nodules of similar histology in the same lobe

MICROSCOPIC DESCRIPTION

would be classified as pT3. Clinical correlation is recommended.
Margins of resection: The bronchial and vascular resection margins are negative.
Direct extension of tumor: Visceral pleural extension for the 2.6 cm in diameter lesion, no direct extension identified for the larger lesion.
Vascular invasion: Not definitively identified.
Regional lymph nodes (pN): pN1. There is metastatic carcinoma in one of three hilar lymph nodes in part A. The separately submitted lymph nodes in parts B, C, D, and E are negative for malignancy.

Distant metastasis (pM): pMX

Other findings: There are inflammatory changes surrounding the tumors, with focally prominent pneumonia surrounding the larger lesion.

Note: This case has been reviewed in Intradepartmental Consultation with all reviewers interpreting the two mass lesions as similar in appearance.

3,4x3,5

DIAGNOSIS

- A. Lung, right upper lobe, excision
- Two adjacent but separate masses with poorly differentiated non-small cell carcinoma (see microscopic description).
- Metastatic carcinoma in one of three (1/3) hilar lymph nodes.
- Bronchial and vascular resection margins negative for malignancy.

- B-E. Lymph nodes, level 11, 2R, 4R, and level 7, excisions
- Negative for malignancy.
-

Source: NCI Genomic Data Commons file ca7091d8-aa76-4c6f-a755-38034f21f2ed (TCGA-43-2581.EB835B34-3938-4ACE-9C89-11EBEFB85DA2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).